Surgical pathology report (de-identified scan), TCGA case TCGA-JY-A93D, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University Health Network, specimen TCGA-JY-A93D-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Consultation Report

Patient Name:	[REDACTED]	Accession #:	[REDACTED]
MRN:	[REDACTED]	Collected:	
DOB:	[REDACTED]	Received:	
Gender:	M	Reported:	
Ordering MD:	[REDACTED]		
Copy To:	[REDACTED]		

Specimen(s) Received

1. Lymph-Node: ST19 Splenic nodes
2. Lymph node: Station 8
3. Esophagogastric Resection: Thoracic esophagus + Proximal stomach with esophageal margin - QS
4. Lymph node: Station 7
5. Lymph node: Station 17
6. Lymph node: Station 16
7. Lymph node: Additional station 7
8. Lymph node: Additional station 8
9. Lymph node: station 4R
10. Esophagus: Final esophageal margin
11. Esophagus: EEA donuts
12. Stomach Resection: Final gastric resection margin

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Esophagus, distal third
C15.5
QJ 4/18/14

Diagnosis

1. Specimen labeled "Lymph node station 19 (splenic nodes)", excision:

Benign fibroadipose tissue.
No lymph node(s) represented for evaluation in the submitted tissue.
There is no evidence of malignancy.

2. Lymph node station 8, excision:

Metastatic adenocarcinoma in one (1) of seven (7) lymph nodes.

3. Thoracic esophagus and proximal stomach, resection:

Invasive adenocarcinoma (3.4 x 3.0 x 1.2 cm), poorly differentiated, arising in the lower esophagus in the background of extensive Barrett's esophagus with focal high-grade dysplasia:
Lymphovascular and perineural invasion are seen.
All evaluated surgical resection margins are negative for carcinoma.
Summary stage (incorporating all parts 1-12): pT2 pN3 pMX
See synoptic report below.

4. Lymph node station 7, excision:

Metastatic adenocarcinoma in one (1) of four (4) lymph nodes.

5. Lymph node station 17, excision:

Metastatic adenocarcinoma in five (5) of sixteen (16) lymph nodes.

[page 2 of 5]
6. Lymph node station 16, excision:

Metastatic adenocarcinoma in four (4) of nine (9) lymph nodes.

7. Additional lymph node station 7, excision:

Metastatic adenocarcinoma in one (1) of one (1) lymph node.

8. Specimen labeled "Additional lymph node station 8", excision:

Benign fibroadipose tissue.

No lymph node(s) represented for evaluation in the submitted tissue.

There is no evidence of malignancy.

9. Lymph node station 4R, excision:

There is no evidence of malignancy in two (2) of two (2) lymph nodes.

10. Final esophageal margin, resection:

Benign squamous mucosa and esophageal wall.

No glandular mucosa seen.

There is no evidence of malignancy.

11. EGA donuts, excision:

Fragment of benign squamous mucosa and esophageal wall.

Fragment of benign gastric corpus-type wall.

There is no evidence of malignancy, atrophy, intestinal metaplasia, or Helicobacter-like organisms.

12. Final gastric margin, resection:

Benign gastric corpus-type wall.

There is no evidence of malignancy, atrophy, intestinal metaplasia, or Helicobacter-like organisms.

Synoptic Data

Data below integrates information from all parts 1-12.

Clinical History:	Barrett's esophagus
Specimen:	Esophagus
	Proximal stomach
Procedure:	Esophagogastrectomy
Primary Tumor Site:	Distal esophagus (lower thoracic esophagus)
Additional Sites Involved by Tumor:	Esophagogastric junction (EGJ)
	Proximal stomach and esophagogastric junction
Relationship of Tumor to Esophagogastric Junction:	Tumor midpoint lies in the distal esophagus and tumor involves the esophagogastric junction
Histologic Type:	Adenocarcinoma
Histologic Grade:	G3: Poorly differentiated
Tumor Size:	Greatest dimension: 3.4 cm
	Additional dimension: 3.0 cm
	Additional dimension: 1.2 cm
Microscopic Tumor Extension:	Tumor invades muscularis propria
Proximal Margin:	Uninvolved by invasive carcinoma
	Uninvolved by dysplasia
Distal Margin:	Uninvolved by invasive carcinoma
	Uninvolved by dysplasia

[page 3 of 5]
Surgical Pathology Consultation Report

Circumferential (Adventitial) or Deep Margin:

Uninvolved by invasive carcinoma
All Margin Status
All margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 3 mm
Closest margin: Circumferential

Treatment Effect:

No prior treatment

Lymph-Vascular Invasion:

Present

Perineural Invasion:

Present

TNM Descriptors:

Not applicable: No TNM prefix applicable

Primary Tumor (pT):

pT2: Tumor invades muscularis propria

Regional Lymph Nodes (pN):

pN3: 7 or more nodes involved

Number of regional lymph nodes examined: 39

Number of regional lymph nodes involved: 14

Distant Metastasis (pM):

Not applicable: Unknown (pMX)

Additional Pathologic Findings:

*Intestinal metaplasia (Barrett's esophagus)

High grade dysplasia

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Clinical History

Esophageal adenocarcinoma; Barrett's

Gross Description

1. The specimen container is labeled with the patient's name and as "Lymph node station 19 (splenic nodes)". The specimen consists of 1 piece of fibroadipose tissue measuring 3.5 x 3.0 x 1.2 cm. No grossly obvious lymph nodes are identified within the tissue.

1A-1C submitted in toto

2. The specimen container is labeled with the patient's name and as "Station 8". The specimen consists of multiple pieces of fibroadipose tissue measuring, in aggregate, 3.5 x 3.0 x 2.2 cm. Within the tissue are multiple possible lymph nodes ranging from 0.1 to 0.4 cm. Representative sections, identified lymph nodes submitted intact and in toto.

2A-2B multiple intact lymph nodes per block

3. The specimen container is labeled with the patient's name and as "Thoracic esophagus and proximal stomach".

RESECTION SPECIMEN: Gastroesophagectomy

FIXATION: Received fresh, placed in formalin. The adventitial surface is painted with silver nitrate.

DIMENSIONS:

Length along lesser curvature: 8.0 cm

Length along greater curvature: 3.5 cm

Circumference of distal gastric margin: 13.0 cm

Circumference of proximal esophageal margin: 5.0 cm

Length of tubular esophagus: 6.0 cm

Width of tubular esophagus: 4.7 cm

TUMOR

LOCATION:

[page 4 of 5]
Surgical Pathology Consultation Report

- Esophagus; extending through GE junction with <5% of tumor in gastric cardia
- CONFIGURATION: Diffuse, circumferential
- DIMENSIONS: Diameters: 3.4 x 3.0 cm
Depth: 1.2 cm
- DESCRIPTIVE CHARACTERISTICS: Poorly defined with a varied appearance. There is a table top lesion (with endoscopic tip stuck in it) at the proximal aspect measuring 1.1 cm in diameter. The majority of the tumor is comprised of a broad based ulcerative lesion measuring 3.0 cm from proximal to distal x 3.4 cm in circumference. The distal edge of this has a nodular appearance in an area measuring 1.1 x 0.9 cm.
- PERFORATION: No
- DISTANCE FROM MARGINS:
- PROXIMAL: 2.5 cm
- DISTAL: 6.5 cm
- RADIAL: 0.3 cm (inked adventitial surface)

ESTIMATED DEPTH OF INVASION: Into muscularis propria

LESIONS IN NONCANCEROUS STOMACH: The stomach mucosa is congested

LYMPH NODES: No perigastric or thoracic lymph nodes are identified within the small fragments of adherent adipose tissue

FROZEN SECTION: Representative section of the esophageal margin was submitted as block 3A

Tissue is stored frozen

Photographs are taken

Representative Sections:

3A frozen section tissue, resubmitted

3B remaining esophageal margin, en face

3C-3Q every other sagittal section of esophagus moving from the greater curvature in a clockwise direction through the anterior portion first (each triplet of blocks contains one full thickness sagittal section from proximal esophagus to just beyond GE junction trisected, with the 1st block containing the proximal portion, the 2nd block containing the midportion and the 3rd block containing the distal portion)

3R-3T stomach

3U-3W gastric margin, en face

4. The specimen container is labeled with the patient's name and as "Station 7". The specimen consists of 1 piece of fibroadipose tissue measuring 4.2 x 3.2 x 1.7 cm. Within the tissue are multiple lymph nodes ranging from 0.1 to 3.3 cm. Representative sections, lymph nodes submitted in toto.

4A multiple intact lymph nodes

4B 1 lymph node, bisected

4C-4D 1 lymph node, bisected

5. The specimen container is labeled with the patient's name and as "Station 17". The specimen consists of 1 piece of adipose tissue consistent with omentum measuring 11.0 x 7.5 x 2.0 cm. The tissue is congested. Within the tissue are multiple lymph nodes ranging from 0.2 to 1.3 cm. Representative sections, lymph nodes submitted in toto.

5A-5D multiple intact lymph nodes

5E 1 lymph node, bisected

6. The specimen container is labeled with the patient's name and as "Station 16". The specimen consists of 1 piece of fibroadipose tissue measuring 11.0 x 5.5 x 1.8 cm. Within the tissue are multiple lymph nodes ranging from 0.1 to 0.6 cm. Representative sections, lymph nodes submitted in toto:

[page 5 of 5]
Surgical Pathology Consultation Report

6A-6B multiple intact lymph nodes

7. The specimen container is labeled with the patient's name and as "Additional station 7". The specimen consists of 2 pieces of fibroadipose tissue measuring, in aggregate, 2.0 x 1.0 x 0.3 cm. No grossly obvious lymph nodes are identified within the tissue.

7A submitted in toto

8. The specimen container is labeled with the patient's name and as "Additional station 8". The specimen consists of 1 piece of fibroadipose tissue measuring 2.2 x 2.3 x 1.0 cm. No grossly obvious lymph nodes are identified within the tissue.

8A-8B submitted in toto

9. The specimen container is labeled with the patient's name and as "Station 4R". The specimen consists of 2 pieces of tan and anthracotic tissue measuring 1.0 and 1.3 cm in maximum dimension.

9A submitted in toto

10. The specimen container is labeled with the patient's name and as "Final esophageal margin". The specimen consists of a ring of mucosa, stapled at one end, measuring 3.5 cm in diameter by 0.5 cm in length. No obvious lesion is identified.

10A tissue abutting staple line

11. The specimen container is labeled with the patient's name and as "EGA donuts". The specimen consists of 2 pieces of pink-tan tissue consistent with mucosa. The smaller piece measures 1.2 x 0.7 x 0.2 cm. The larger piece is a circular piece held together with blue suture material with a diameter of 4.0 cm and a length of 0.9 cm. No gross lesions are identified. Submitted in toto:

11A smaller piece

11B larger piece

12. The specimen container is labeled with the patient's name and as "Final gastric resection margin". The specimen consists of a wedge resection of stomach, stapled along both edges. The specimen has a diameter of 6.5 cm and a maximum length of 3.3 cm. The staple lines measuring 8.0 cm each. One of the staple lines is partially opened. Adherent adipose tissue measures 3.5 x 2.5 x 0.1 cm. The gastric mucosa is congested at the open staple line but is otherwise unremarkable. No lymph nodes are identified within the adipose tissue. Representative sections:

12A tissue along partially open staple line

12B ventral sections

12C tissue along opposite staple line

Quick Section Diagnosis

Part 3: Thoracic esophagus and proximal stomach; esophageal margin for QS: Esophageal margin negative for carcinoma

Result reported at

Source: NCI Genomic Data Commons file b5cff3fa-951d-4089-9070-13222a6ed33d (TCGA-JY-A93D.F05374ED-C58F-4EE9-B593-846451113530.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).